Gene-level copy-number profile of tumor specimen TCGA-76-6280-01A from TCGA case TCGA-76-6280, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,931 days).
Specimen TCGA-76-6280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.64cc4c4d-01d2-4fde-8f6f-16c368073b85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-76-6280-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/09937e72-3c65-4b0f-b98b-70b0fe64f135

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 7,055; copy number 2: 45,114; copy number 3: 7,601; copy number 4: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-76-6280-01A-21D-1842-01): tumor purity 0.79, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,479,827–232,860,605, 15 genes (within-gene range 0–1): ECEL1, PRSS56, CHRND, CHRNG, TIGD1, MIR5001, EIF4E2, AC073254.1, EFHD1, RN7SL359P, GIGYF2, EEF1B2P7, AC064852.1, KCNJ13, RNU6-107P.
- chr5:85,420,028–86,087,847, 9 genes: AC010486.1, AC010486.2, AC010486.3, RPL5P17, AC026700.1, AC010595.1, RPS2P25, AC026414.1, PTP4A1P4.
- chr5:104,383,298–105,392,970, 1 gene (within-gene range 0–2): AC099520.1.
- chr5:104,773,641–105,246,364, 4 genes (within-gene range 0–2): AC099520.2, RNU6-334P, AC091987.1, RAB9BP1.
- chr5:165,905,126–166,382,599, 4 genes: AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,669. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
